TCGA case TCGA-UT-A97Y — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Asbestos Diseases Research Institute. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9ce1f62-2df1-4974-868b-d075781ce282

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 81 years; Vital status: Dead; Days to death: 144 days.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 81.9 years (29,905 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 144 days; Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Other.

Molecular and laboratory tests
- Creatinine 0.98 mg/dL [Blood test normal range lower: 0.34; Blood test normal range upper: 1.13].

Exposures
- Exposure type: Asbestos; Exposure duration years: 30; Exposure source: Secondary.
- Occupation type: General Office Clerks.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Grandparent; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UT-A97Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-UT-A97Y-01A-02-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-UT-A97Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UT-A97Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Office worker; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 144 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 144 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 144 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UT-A97Y-01A-21D-A39Q-01): tumor purity 0.23, ploidy 1.81, whole-genome doublings 0.
